Gene-level copy-number profile of tumor specimen TCGA-BR-8361-01A from TCGA case TCGA-BR-8361, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.2 years (25,999 days).
Specimen TCGA-BR-8361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4681cf59-aebb-4382-8ee8-ff7a80365cf3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8361-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a4d5e97-afcb-4c73-b9fa-8c65c3786d9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 5,034; copy number 2: 48,475; copy number 3: 6,291; copy number 4: 7; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8361-01A-11D-2338-01): tumor purity 0.64, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:816,615–896,436, 3 genes (within-gene range 0–3): SUN1, GET4, AC073957.3.
- chr17:11,977,439–12,143,830, 6 genes (within-gene range 0–2): ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:8,822,621–8,915,276, 2 genes, copy number 8 (within-gene range 3–8): A2ML1, AC006581.2.

Autosomal genes at a single copy (total copy number 1): 5,014. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
